Somatic mutation profile of tumor specimen MBCProject_0934_T1_WES (aliquot MBCProject_0934_T1_WES_1) from CMI case MBCProject_0934, project CMI-MBC: Count Me In (CMI): The Metastatic Breast Cancer (MBC) Project. Sex at birth: female; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; Age at diagnosis: 43.3 years (15,807 days).
Specimen MBCProject_0934_T1_WES: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Breast; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 2d84051e-dd0d-4981-9b10-b3457aa1a273.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MBCProject_0934_SALIVA (Saliva), aliquot MBCProject_0934_SALIVA_1; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/43133924-f822-43be-8a4a-39d96c3ec13a

The open-access MAF lists 62 somatic variants for this specimen: 47 protein-altering or splice-affecting, 8 silent, 7 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 37, Silent 8, Nonsense Mutation 5, 5'UTR 3, Intron 3, In Frame Del 2, Nonstop Mutation 1, Frame Shift Del 1, 5'Flank 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.463_468del p.T155_R156del | In Frame Del (DEL) | VAF 8/87 reads (9%) | hotspot (GDC flag); catalogued as rs1555526166; ClinVar: uncertain significance; called by mutect2, pindel
- AMACR | c.511C>G p.R171G | Missense Mutation (SNP) | VAF 20/300 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV59461166; called by muse, mutect2
- ARHGEF6 | c.634A>T p.N212Y | Missense Mutation (SNP) | VAF 12/160 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51692414; called by muse, mutect2
- ATAD2 | c.2689G>C p.D897H | Missense Mutation (SNP) | VAF 12/128 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.103); catalogued as COSV54877146; called by muse, mutect2
- CACNA1D | c.5930C>T p.S1977L (on ENST00000350061 / NM_001128840.3; = p.S1997L on NM_000720.4) | Missense Mutation (SNP) | VAF 8/76 reads (11%) | SIFT tolerated, low confidence (0.52); PolyPhen benign (0.009); catalogued as rs202077075, COSV55441250; called by mutect2, varscan2
- CNBD2 | c.833C>A p.P278H | Missense Mutation (SNP) | VAF 6/68 reads (9%) | SIFT deleterious (0.04); PolyPhen benign (0.109); catalogued as rs1165541806, COSV100839109; called by muse, mutect2
- CNPPD1 | c.239A>C p.K80T | Missense Mutation (SNP) | VAF 10/137 reads (7%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.906); catalogued as rs1226937396; called by muse, mutect2
- EFCAB1 | c.250G>T p.V84L | Missense Mutation (SNP) | VAF 9/104 reads (9%) | SIFT tolerated (0.13); PolyPhen benign (0.015); catalogued as rs1262976266; called by muse, mutect2
- GJC1 | c.798G>C p.R266S | Missense Mutation (SNP) | VAF 6/85 reads (7%) | SIFT tolerated (0.1); PolyPhen benign (0.01); catalogued as COSV57912174; called by muse, mutect2
- NDUFS3 | c.512G>C p.W171S | Missense Mutation (SNP) | VAF 17/262 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99772229; called by muse, mutect2
- NR2E1 | c.545C>T p.T182M | Missense Mutation (SNP) | VAF 27/373 reads (7%) | SIFT deleterious (0.03); PolyPhen benign (0.176); catalogued as rs555952873; called by muse, mutect2
- OR2AK2 | c.588G>T p.E196D | Missense Mutation (SNP) | VAF 3/25 reads (12%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.906); catalogued as COSV100823069, COSV100823985; called by muse, mutect2
- PCDHA5 | c.2155G>A p.A719T | Missense Mutation (SNP) | VAF 22/208 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.734); catalogued as rs1554129666, COSV65350345; called by muse, mutect2
- QPRT | c.682-1G>A p.X228_splice | Splice Site (SNP) | VAF 4/13 reads (31%) | catalogued as COSV54880034; called by mutect2, varscan2
- RELN | c.4057G>A p.E1353K | Missense Mutation (SNP) | VAF 20/282 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.925); catalogued as rs768750792, COSV59027550; called by muse, mutect2
- RNFT2 | c.89G>A p.R30H | Missense Mutation (SNP) | VAF 13/128 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.791); catalogued as rs996313242; called by muse, varscan2
- UTP14A | c.1817G>C p.R606T | Missense Mutation (SNP) | VAF 12/218 reads (6%) | SIFT tolerated (0.23); PolyPhen benign (0.02); catalogued as COSV99057707; called by muse, mutect2
- ARHGAP32 | c.2495A>T p.N832I (on ENST00000310343 / NM_001378025.1; = p.N483I on NM_014715.4) | Missense Mutation (SNP) | VAF 6/91 reads (7%) | SIFT tolerated (0.21); PolyPhen benign (0.022); called by muse, mutect2
- BMS1 | c.3592G>C p.V1198L | Missense Mutation (SNP) | VAF 6/50 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by mutect2, varscan2
- COL6A6 | c.3233A>C p.H1078P | Missense Mutation (SNP) | VAF 12/148 reads (8%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.793); called by muse, mutect2
- CTR9 | c.1794G>C p.Q598H | Missense Mutation (SNP) | VAF 16/158 reads (10%) | SIFT tolerated (0.2); PolyPhen benign (0.013); called by muse, mutect2
- CYB5R4 | c.32C>G p.A11G | Missense Mutation (SNP) | VAF 22/246 reads (9%) | SIFT tolerated (0.07); PolyPhen benign (0.007); called by muse, mutect2
- FAM166B | c.631C>T p.Q211* (on ENST00000399742 / NM_001164310.3; = p.A188V on NM_001099951.4) | Nonsense Mutation (SNP) | VAF 8/36 reads (22%) | called by muse, mutect2, varscan2
- FBN1 | c.5338G>T p.G1780* | Nonsense Mutation (SNP) | VAF 24/402 reads (6%) | called by muse, mutect2
- FUT11 | c.244_252del p.S82_G84del | In Frame Del (DEL) | VAF 16/80 reads (20%) | called by mutect2, pindel, varscan2
- FZD1 | c.989G>A p.C330Y | Missense Mutation (SNP) | VAF 13/161 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- GPR25 | c.784G>A p.A262T | Missense Mutation (SNP) | VAF 9/136 reads (7%) | SIFT tolerated (0.41); PolyPhen benign (0.013); called by muse, mutect2
- KIF4B | c.1574A>C p.E525A | Missense Mutation (SNP) | VAF 10/120 reads (8%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.78); called by muse, mutect2
- KIRREL1 | c.2030A>C p.D677A | Missense Mutation (SNP) | VAF 12/101 reads (12%) | SIFT tolerated (0.07); PolyPhen benign (0.091); called by muse, mutect2, varscan2
- MTHFD1L | c.321C>G p.D107E | Missense Mutation (SNP) | VAF 14/96 reads (15%) | SIFT tolerated (0.1); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- NID1 | c.385T>A p.S129T | Missense Mutation (SNP) | VAF 17/115 reads (15%) | SIFT tolerated (0.3); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- OGFR | c.85G>T p.E29* | Nonsense Mutation (SNP) | VAF 10/130 reads (8%) | called by muse, mutect2
- OTOF | c.5994A>G p.*1998Wext*66 (on ENST00000272371 / NM_194248.3; = p.*1231Wext*66 on NM_004802.4) | Nonstop Mutation (SNP) | VAF 11/155 reads (7%) | called by muse, mutect2
- PCCB | c.406G>C p.A136P | Missense Mutation (SNP) | VAF 9/121 reads (7%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.864); called by muse, mutect2
- PRKG1 | c.37A>C p.M13L | Missense Mutation (SNP) | VAF 13/173 reads (8%) | SIFT tolerated (0.25); PolyPhen benign (0); called by muse, mutect2
- RAET1L | c.19C>A p.P7T | Missense Mutation (SNP) | VAF 10/86 reads (12%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- RAP1B | c.16C>G p.L6V | Missense Mutation (SNP) | VAF 10/86 reads (12%) | SIFT tolerated (0.3); PolyPhen benign (0.197); called by mutect2, varscan2
- RYR2 | c.328C>T p.H110Y | Missense Mutation (SNP) | VAF 17/165 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.756); called by muse, mutect2
- SAMM50 | c.1180C>T p.H394Y | Missense Mutation (SNP) | VAF 32/146 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SF3A1 | c.722A>G p.D241G | Missense Mutation (SNP) | VAF 6/115 reads (5%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.679); called by muse, mutect2
- SHROOM3 | c.4966_4969del p.S1656Lfs*26 | Frame Shift Del (DEL) | VAF 29/236 reads (12%) | called by pindel, varscan2
- SLC30A9 | c.1330A>G p.T444A | Missense Mutation (SNP) | VAF 10/146 reads (7%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.678); called by muse, mutect2
- SLC36A1 | c.132C>A p.S44R | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT tolerated (0.4); PolyPhen benign (0.043); called by muse, mutect2, varscan2
- SPTAN1 | c.1189G>T p.E397* | Nonsense Mutation (SNP) | VAF 16/208 reads (8%) | called by muse, mutect2
- TBC1D19 | c.1102G>A p.G368R | Missense Mutation (SNP) | VAF 5/41 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, varscan2
- UBE3B | c.1672G>T p.E558* | Nonsense Mutation (SNP) | VAF 8/79 reads (10%) | called by muse, mutect2
- ZNF653 | c.1783T>G p.F595V | Missense Mutation (SNP) | VAF 8/130 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- CDC42EP4 | c.327G>T p.S109= | Silent (SNP) | VAF 21/116 reads (18%) | called by muse, mutect2, varscan2
- CLCN7 | c.474C>T p.V158= | Silent (SNP) | VAF 22/292 reads (8%) | called by muse, mutect2
- GRM1 | c.2124C>A p.I708= | Silent (SNP) | VAF 9/74 reads (12%) | catalogued as rs1403824525; called by muse, mutect2, varscan2
- HSD17B1 | c.513G>A p.A171= | Silent (SNP) | VAF 34/260 reads (13%) | called by muse, mutect2, varscan2
- ITPR1 | c.2067G>A p.E689= (on ENST00000354582; = p.E674= on NM_002222.7) | Silent (SNP) | VAF 11/169 reads (7%) | called by muse, mutect2
- NSD3 | c.537A>G p.E179= | Silent (SNP) | VAF 10/155 reads (6%) | called by muse, mutect2
- TTN | c.26046A>T p.I8682= (on ENST00000591111; = p.I7755= on NM_133378.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 8/66 reads (12%) | called by muse, varscan2
- ZNF862 | c.870C>T p.I290= | Silent (SNP) | VAF 6/50 reads (12%) | catalogued as COSV56224968; called by muse, varscan2
- CCDC191 | c.-3A>G | 5'UTR (SNP) | VAF 24/384 reads (6%) | catalogued as rs746300908; called by muse, mutect2
- CD79A | c.-6G>T | 5'UTR (SNP) | VAF 18/246 reads (7%) | called by muse, mutect2
- CTAGE13P | chr6:168293882 T>C | 5'Flank (SNP) | VAF 22/118 reads (19%) | called by muse, mutect2, varscan2
- SDHC | c.-4C>A | 5'UTR (SNP) | VAF 34/330 reads (10%) | catalogued as COSV100337781; called by muse, mutect2
- SIGLEC10 | c.755-19T>C | Intron (SNP) | VAF 3/21 reads (14%) | called by muse, mutect2
- TNFRSF17 | c.278-545G>A | Intron (SNP) | VAF 3/29 reads (10%) | called by muse, mutect2
- VPS28 | c.37+30C>T | Intron (SNP) | VAF 9/93 reads (10%) | catalogued as rs781797924; called by muse, mutect2, varscan2
